Somatic mutation profile of cancer-model specimen HCM-BROD-0870-C43-85N (Adherent Cell Line, passage 12; aliquot HCM-BROD-0870-C43-85N-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0870-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.3 years (18,388 days).
Specimen HCM-BROD-0870-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d64daaa8-a99e-4485-86a9-065e1db33634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0870-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0870-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/928224eb-5697-4776-96c7-ca7b86939829

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK5 | c.769C>T p.R257C (on ENST00000354567 / NM_174858.3; = p.R231C on NM_012093.4) | Missense Mutation (SNP) | VAF 189/400 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745816196; called by muse, mutect2, varscan2
- CASQ2 | c.1058C>A p.P353Q | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54771295; called by muse, mutect2
- JRK | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 32/708 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as rs782448482; called by muse, mutect2
- KDM6B | c.3883_3885del p.X1295_splice | Splice Site (DEL) | VAF 126/320 reads (39%) | catalogued as rs753991103; called by pindel, varscan2
- OR51G1 | c.512G>C p.C171S | Missense Mutation (SNP) | VAF 155/340 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1199808090; called by muse, mutect2, varscan2
- PPP1R1C | c.178del p.E60Nfs*20 | Frame Shift Del (DEL) | VAF 88/228 reads (39%) | catalogued as rs997821451; called by mutect2, pindel, varscan2
- SMARCAD1 | c.2303dup p.N768Kfs*28 | Frame Shift Ins (INS) | VAF 80/212 reads (38%) | catalogued as rs750056186; called by mutect2, varscan2
- TTN | c.8674G>A p.E2892K (on ENST00000591111; = p.E2846K on NM_003319.4) | Missense Mutation (SNP) | VAF 126/269 reads (47%) | PolyPhen benign (0.195); catalogued as rs763393324; called by muse, mutect2, varscan2
- CDCA2 | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MOG | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 216/556 reads (39%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MX2 | c.1114_1123del p.E372Pfs*15 | Frame Shift Del (DEL) | VAF 99/274 reads (36%) | called by mutect2, pindel, varscan2
- PCDH1 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 265/605 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDP2 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 17/429 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2
- SLCO1B3 | c.29C>G p.T10R | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TAF3 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- ZNF470 | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 21/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- EPHB4 | c.1053C>A p.G351= | Silent (SNP) | VAF 153/580 reads (26%) | called by muse, mutect2, varscan2
- FBRSL1 | c.1569C>T p.G523= | Silent (SNP) | VAF 237/571 reads (42%) | catalogued as rs774021267, COSV55516874; called by muse, mutect2, varscan2
- FNDC5 | c.615G>T p.G205= | Silent (SNP) | VAF 85/600 reads (14%) | called by muse, varscan2
- HERC2 | c.13587C>T p.H4529= | Silent (SNP) | VAF 26/601 reads (4%) | catalogued as rs755582126; called by muse, mutect2
- LGI1 | c.1386C>G p.G462= | Silent (SNP) | VAF 18/560 reads (3%) | called by muse, mutect2
- MTTP | c.225T>C p.D75= | Silent (SNP) | VAF 128/302 reads (42%) | called by muse, mutect2, varscan2
- MUC16 | c.26649G>A p.V8883= | Silent (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- GP6 | c.*117C>T | 3'UTR (SNP) | VAF 240/508 reads (47%) | catalogued as rs745470892; called by muse, mutect2, varscan2
- NACA | c.70+4413A>G | Intron (SNP) | VAF 190/411 reads (46%) | catalogued as rs1446200617; called by muse, mutect2, varscan2
